Somatic mutation profile of tumor specimen TARGET-30-PANZPV-01A (aliquot TARGET-30-PANZPV-01A-01W) from TARGET case TARGET-30-PANZPV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Liver; Age at diagnosis: 4.8 years (1,757 days).
Specimen TARGET-30-PANZPV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1fe2357-e5cd-4066-bc82-8857789e657b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANZPV-10A (Blood Derived Normal), aliquot TARGET-30-PANZPV-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4e78a18-eb24-44ab-b86b-d13314972f96

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELOA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as COSV55297292; called by muse, mutect2, varscan2
- SLC52A2 | c.1277dup p.T427Dfs*18 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | catalogued as rs781950790; called by pindel, varscan2
- ARHGAP35 | c.4335dup p.G1446Rfs*70 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel
- DNTT | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 20/409 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.257); called by muse, mutect2
- FAM162A | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ITSN2 | c.4311C>A p.H1437Q | Missense Mutation (SNP) | VAF 31/919 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
